Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA0N, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA0N-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061h3
Site: Testis NOS C62.9
JW 3/3/14

Date of procurement

Pathohistological diagnosis

Seminoma testis (pT2 NXMX)

Description:

Testicle with cut tumor, size 8:6:5 cm, and 8 cm long funiculus was received. The tumor has irregular edges, is white to brown in color, of medium consistency and is 8:5:4 cm in size. Histologically, the tumor is made of solid seats and tumor cell traces with round and oval bright nuclei in which we see small nuclei and scarce, bright and pink cytoplasm. Inside the tumor, at microscope's large visual field, we see 3-4 mitosis. Around tumor seats we find connecting tissue containing moderately abundant lymphocyte infiltrates. Several channels adjacent to tumor are coated with unclassified intratubular germ cell neoplasia (IGCNU). Performed imunohistochemical dying (positive PLAP in all tumor cells and in unclassified intratubular germ cell neoplasia) with morphological examination indicates that this is a malign testicular tumor of germ origin, seminoma.

The tumor infiltrates tunica albuginea and is present in lumens of several blood vessels inside tunica albuginea. The tumor was not detected in funiculus.

Source: NCI Genomic Data Commons file d4017c52-11b7-4459-9972-d0e6f1739733 (TCGA-ZM-AA0N.9770AC5E-899D-4337-ABBD-A59E5FCF229C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).